Somatic mutation profile of tumor specimen TCGA-74-6577-01A (aliquot TCGA-74-6577-01A-11D-1845-08) from TCGA case TCGA-74-6577, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.3 years (18,740 days).
Specimen TCGA-74-6577-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0009beaa-eafe-4c63-826d-16a81d3602a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-74-6577-10A (Blood Derived Normal), aliquot TCGA-74-6577-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f201f479-0995-4a24-9fa3-c771d3ff57b6

The open-access MAF lists 36 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 2, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1007dup p.Y336* | Nonsense Mutation (INS) | VAF 34/90 reads (38%) | hotspot (GDC flag); catalogued as CI983205; called by mutect2, pindel, varscan2
- ABLIM3 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs781087991, COSV58641446; called by muse, mutect2, varscan2
- APPBP2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV50026529; called by muse, mutect2, varscan2
- AQP2 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303076207, CM062427, CM970099, COSV52229790; called by muse, mutect2, varscan2
- ATP9B | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149013492, COSV56950428; called by muse, mutect2, varscan2
- BAZ1A | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375235365; called by muse, mutect2, varscan2
- CD300LD | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201880339; called by muse, mutect2, varscan2
- CILP2 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1183397259, COSV52274663; called by muse, mutect2, varscan2
- FAM47C | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs782267927, COSV63724853, COSV63726402; called by muse, mutect2, varscan2
- FRMD7 | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53745895; called by muse, mutect2, varscan2
- GJD2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51747974; called by muse, mutect2, varscan2
- GLI2 | c.4529G>T p.G1510V (on ENST00000361492 / NM_001374353.1; = p.G1527V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58040837; called by muse, mutect2, varscan2
- HRNR | c.8371G>A p.G2791S | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV64257268; called by muse, mutect2, varscan2
- IGHM | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); catalogued as rs781852051; called by muse, mutect2, varscan2
- KMT2C | c.2266G>A p.G756R | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1362481149, COSV51434680; called by muse, mutect2, varscan2
- NACA | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV63269700; called by muse, mutect2, varscan2
- NLRP4 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as rs140263319, COSV56710538; called by muse, mutect2, varscan2
- OR4K2 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53849281, COSV53851202; called by muse, mutect2, varscan2
- PRUNE2 | c.2408T>A p.F803Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV65041055; called by muse, mutect2, varscan2
- PTPRN2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs759890478, COSV67020053; called by muse, mutect2, varscan2
- RBCK1 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs546711324, COSV62292198; called by muse, mutect2, varscan2
- SERPINB7 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV60533676; called by muse, mutect2, varscan2
- SHOC1 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59497965, COSV59500694; called by muse, mutect2, varscan2
- STAG2 | c.1908C>G p.Y636* | Nonsense Mutation (SNP) | VAF 25/43 reads (58%) | catalogued as COSV54357332, COSV54359640, COSV54363691; called by muse, mutect2, varscan2
- SVEP1 | c.6722C>T p.P2241L | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV52838696; called by muse, mutect2, varscan2
- TTC5 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs200172808, COSV51870771; called by muse, mutect2, varscan2
- UGT2B4 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs1314997496, COSV59316881; called by muse, mutect2, varscan2
- DDX3X | c.1890_1892dup p.S630dup (on ENST00000399959; = p.S631dup on NM_001356.5) | In Frame Ins (INS) | VAF 16/28 reads (57%) | called by mutect2, varscan2
- MYO6 | c.1246_1249del p.A416Tfs*20 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2
- PAPPA | c.2100T>C p.H700= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV60282334; called by muse, mutect2, varscan2
- PKD1L1 | c.6504G>A p.L2168= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as COSV56963810; called by muse, mutect2, varscan2
- S1PR2 | c.135C>T p.C45= | Silent (SNP) | VAF 54/183 reads (30%) | catalogued as rs758137994, COSV58485370; called by muse, mutect2, varscan2
- SEC14L5 | c.1602G>A p.S534= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs772832989, COSV52038183; called by muse, mutect2, varscan2
- SEMA3G | c.759G>A p.S253= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1161131155, COSV51595395; called by muse, mutect2, varscan2
- STK32A | c.666G>A p.P222= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs368677802; called by muse, mutect2, varscan2
